Gene-level copy-number profile of tumor specimen REBC-ADKH-TTP1-A from REBC case REBC-ADKH, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: male; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-ADKH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 96e9d4e7-2b32-4741-bcec-5c38eeb652b0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-ADKH-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/a2634752-46cf-4d96-889e-57de57533a00

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,742; copy number 2: 55,135; copy number 3: 23; copy number 4: 8; copy number 5: 8.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:196,739,857–196,832,647, 1 gene, copy number 5 (within-gene range 2–5): PAK2.
- chr3:196,784,980–196,785,086, 1 gene, copy number 5: RNU6-42P.
- chr13:100,027,769–100,088,950, 3 genes, copy number 5: NDUFA12P1, PCCA-DT, ASNSP3.
- chr15:77,041,404–77,083,984, 3 genes, copy number 5 (within-gene range 2–5): TSPAN3, AC090181.1, AC090181.3.

Autosomal genes at a single copy (total copy number 1): 886. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
